CCDI case PBCNUN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9d9e3f33-2fcf-4d7a-81c0-46aa16fa093d

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.5 years (902 days).

Biospecimens (3 samples)
- Sample 0DX2CC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX2CV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DX2CZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
